Surgical pathology report (de-identified scan), TCGA case TCGA-97-8176, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-8176-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. F/S RIGHT MIDDLE LOBE LYMPH NODE
2. RIGHT LOWER LOBE ATTACHED TO DIAPHRAGM
3. RIGHT RIB 8
4. LEVEL 9 LYMPH NODE
5. LEVEL 11 LYMPH NODE
6. LEVEL 7 LYMPH NODE, RIGHT
7. HILAR LYMPH NODE 11, RIGHT
8. LEVEL 11 BRONCHUS INTERMEDIUS
9. HIGHEST LEVEL 11 LYMPH NODE
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

DIAGNOSIS:

- 1. LYMPH NODE, RIGHT MIDDLE LOBE: BIOPSY**
- METASTATIC ADENOCARCINOMA INVOLVING ONE LYMPH NODE (1/1).

- 2. LUNG, RIGHT LOWER LOBE: LOBECTOMY**
- ADENOCARCINOMA, ACINAR PREDOMINANT (7 CM), SEE NOTE.
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- THE TUMOR DIRECTLY INVADES THE DIAPHRAGM.

Note: The tumor consists of acinar (50%), papillary (30%), micropapillary (10%) and solid (10%) components. There is prominent extracellular mucin. Results of mutational studies will be reported in addenda.

- 3. RIB, RIGHT 8TH: EXCISION**
- BONE AND BONE MARROW WITH TRILINEAGE HEMATOPOESIS.

- 4. LYMPH NODE, LEVEL 9: BIOPSY**
- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

- 5. LYMPH NODE, LEVEL 11: BIOPSY**

[page 2 of 8]
- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

6. LYMPH NODE, LEVEL 7: BIOPSY

- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

7. LYMPH NODE, LEVEL 11, RIGHT HILAR: BIOPSY

- METASTATIC ADENOCARCINOMA INVOLVING ONE LYMPH NODE (1/1).

8. LYMPH NODE, LEVEL 11, BRONCHUS INTERMEDIUS: BIOPSY

- METASTATIC ADENOCARCINOMA INVOLVING ONE LYMPH NODE (1/1).

9. LYMPH NODE, LEVEL 11, HIGHEST: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

Specimens: 1: F/S RIGHT MIDDLE LOBE LYMPH NODE

2: RIGHT LOWER LOBE ATTACHED TO DIAPHRAGM

3: RIGHT RIB 8

4: LEVEL 9 LYMPH NODE

5: LEVEL 11 LYMPH NODE

6: LEVEL 7 LYMPH NODE, RIGHT

7: HILAR LYMPH NODE 11, RIGHT

8: LEVEL 11 BRONCHUS INTERMEDIUS

9: HIGHEST LEVEL 11 LYMPH NODE

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

right lower

Procedure: Lobectomy

Specimen Laterality: Right

Tumor Site: Lower lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

7cm

Visceral Pleura Invasion: Present

Tumor Extension: Diaphragm

MARGINS

Bronchial Margin

**Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by
invasive carcinoma**

**Bronchial Margin Involvement by Squamous Cell Carcinoma in situ
(CIS): Not applicable**

[page 3 of 8]
Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Present

LYMPH NODES

Extranodal Extension: Not identified

STAGE (pTNM)

Primary Tumor (pT):

pT3: Tumor greater than 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor of any size in the main bronchus less than 2 cm distal to the carina but without involvement of the carina; or Tumor of any size associated atelectasis or obstructive pneumonitis of the entire lung; or Tumors of any size with separate tumor nodule(s) in the same lobe

Regional Lymph Nodes (pN)

pN1: Metastasis in ipsilateral peribronchial and / or ipsilateral hilar lymph nodes, and intrapulmonary nodes including involvement by direct extension

Number Examined

11

Number Involved

1

1

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

ex-smoker (40 pack-years) with a 6 cm RLL mass.

MACROSCOPIC DESCRIPTION:

The specimen is received in formalin, in nine parts, each labeled with the patient's name.

1. Part one is received fresh, labeled 'middle lobe lymph node'. It consists of seven irregular fragments of tan-brown tissue ranging from 0.2 cm to 0.3 cm, and measuring 1 x 0.5 x 0.2 cm. Totally frozen and submitted in one cassette.

2. Part two is received fresh, labeled 'right lower lobe attached to diaphragm'. It consists of a right lower lobe of lung with attached segment of diaphragm measuring 15.5 x 10.5 x 7 cm. The bronchial margin has 2 cm diameter and vascular margin has 1.2 cm diameter. The pleura is gray-pink, glistening and mottled moderately with fine black streaks, and reveals a puckered area measuring 6.5 cm in

[page 4 of 8]
greatest dimension and located at the lower lateral aspect of the lobe. The specimen is received pre-cut and at the pre-cut area there is a gray-white firm tumor measuring 7 x 6.5 x 5.5 cm, located at the lower area of the lobe, 4 cm from bronchial margin. Cut surface of the mass is gray-tan and necrotic. The attached diaphragm measures 5 x 5 x 1 cm. One surface of the diaphragm is attached to the lung and the other surface is pink and glistening, grossly appears to be free of the invasion. The outer surface of diaphragm, vascular and bronchial margins and staple line margin are inked in black. Representative sections are submitted.

3. Part three is received in formalin, labeled 'right rib #8'. It consists of one piece of pink-red rib measuring 1.8 x 1.5 x 1 cm. Representative sections are submitted in one cassette following decalcification.

4. Part four is received in saline, labeled 'level 9 lymph node'. It consists of multiple anthracotic lymph nodes ranging from 0.2 up to 1 cm in greatest dimension. Entire lymph nodes are submitted.

5. Part five is received in saline, labeled 'level 11 lymph node'. It consists of multiple anthracotic lymph nodes ranging from 0.2 up to 0.5 cm in greatest dimension. Entire lymph nodes are submitted.

6. Part six is received in saline, labeled 'level 7 lymph node'. It consists of anthracotic lymph nodes ranging from 0.2 up to 1.2 cm in greatest dimension. Entire lymph nodes are submitted.

7. Part seven is received in saline, labeled 'hilar lymph node #11'. It consists of one anthracotic lymph node measuring 1.8 x 1.5 x 0.3 cm. The specimen is bisected and entirely submitted.

8. Part eight is received in saline, labeled 'level 11 Bronchus-Intermedius'. It consists of one lymph node measuring 2.5 x 1.5 x 1.2 cm. The lymph node is bisected and entirely submitted in two cassettes.

9. Part nine is received in saline, labeled 'highest level 11 lymph node'. It consists of two anthracotic lymph nodes ranging from 0.3 up to 0.5 cm in greatest dimension. Entire specimen is submitted.

SUMMARY OF SECTIONS:

[page 5 of 8]
1A totally frozen and submitted
2A bronchial margin, shaved
2B vascular margin, shaved
2C-2F tumor with overlying puckered pleura
2G-2H tumor with diaphragm
2I tumor with adjacent normal parenchyma
2J staple line margin
3A representative
4A three lymph nodes
4B one lymph node, bisected
5A-5B entire lymph nodes
6A-6C entire lymph nodes
7A entire lymph node, bisected
8A-8B entire lymph node, bisected
9A two lymph nodes

SPECIAL PROCEDURES:

Decalcification

INTRA - OPERATIVE CONSULTATION:

1. Right middle lobe lymph node; frozen section
Metastatic carcinoma, favor adenocarcinoma. Results reported by

[REDACTED]

ADDENDUM #1 FOR MOLECULAR TESTS:

KRAS, EGFR and ALK FISH were sent on [REDACTED] for patient ,
[REDACTED] The test is to be performed on tissue from case

[page 6 of 8]
██████████ The case report, slides, and blocks for the cited accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 2D appropriate to the specifications of the ordered molecular analysis. x1 H&E and x9 unstained slides were prepared and forwarded to ██████████ where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

Addendum #1 performed by

ADDENDUM #2:

INTEGRATED ONCOLOGY

MOLECULAR ONCOLOGY

KRAS MUTATION ANALYSIS

Body Site: Right lower lobe of lung
Specimen Type: Slides
Clinical Data: Adenocarcinoma

RESULTS: Positive for a p.G12S (c.34G>A) mutation in codon 12 of the KRAS gene.

INTERPRETATION:

Mutations in the KRAS gene are reported to correlate with poor prognosis and resistance to tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer.

COMMENT:

KRAS mutations occur in 15-30% of non-small-cell lung cancer (NSCLC) patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are

[page 7 of 8]
expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected.

This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

[illegible]

[page 8 of 8]
[REDACTED]

[REDACTED]

Addendum #2 performed by

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 618cc8f7-006c-49b0-b4a7-c14cfb2c618f (TCGA-97-8176.348AB6F0-FCAE-41CE-AE5C-0F0D3C3FD40F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).